Gene-level copy-number profile of tumor specimen TCGA-BK-A0CC-01B from TCGA case TCGA-BK-A0CC, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 69.8 years (25,479 days).
Specimen TCGA-BK-A0CC-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.7a52efc5-0d32-4147-a2a0-67576bb190b7.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BK-A0CC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 358 have no estimate.
https://portal.gdc.cancer.gov/files/48d97bb1-b267-4776-8e6f-cd8f509012de

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 526; copy number 1: 15,514; copy number 2: 37,509; copy number 3: 6,307; copy number 4: 391; copy number 5: 3; copy number 6: 12; copy number 8: 2; copy number 10: 1.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BK-A0CC-01A-21D-A275-01): tumor purity 0.67, ploidy 5.33, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:94,555,054–94,640,249, 3 genes (within-gene range 0–1): PCAT7, FBP2, FBP1.
- chr17:2,322,396–2,336,657, 2 genes: TSR1, SNORD91A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:140,678,064–140,701,150, 1 gene, copy number 5: TRIM42.
- chr4:49,486,926–49,589,529, 12 genes, copy number 6: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr6:158,237,336–158,242,797, 1 gene, copy number 5: SRP72P2.
- chr6:158,296,671–158,303,372, 1 gene, copy number 5: AL360169.3.
- chr10:95,109,136–95,111,642, 1 gene, copy number 10: AL157834.1.
- chr22:23,261,782–23,265,005, 2 genes, copy number 8: RN7SL263P, FBXW4P1.

Autosomal genes at a single copy (total copy number 1): 13,098. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
